Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A3XX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A3XX-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):

(Age:

Race:

Specimen #:

Taken:

Received:

Reported:

SPECIMEN:

A: SENTINEL NODE #1 B: LEFT BREAST TISSUE

1CD-03
carcinoma, infiltrating,
ductal, NOS

8600/3

FINAL DIAGNOSIS:

Site: breast, NOS C50.9

5-23-12

A. LYMPH NODE, SENTINEL #1, BIOPSY:

- ONE (1) LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA BY H&E AND IMMUNOSTAINS.

B. BREAST, LEFT, MASTECTOMY:

- TUMOR TYPE: INFILTRATING DUCTAL CARCINOMA.
- NOTTINGHAM GRADE: 3 OUT OF 3.
- NOTTINGHAM SCORE: 8 OUT OF 9 (Tubules= 3, Nuclei= 2, Mitoses= 3 mitotic count 22 per 10 HPF at 40x power)
- TUMOR SIZE (GREATEST DIMENSION): 2.2 CM (MEASURED GROSSLY)
- TUMOR NECROSIS: PRESENT IN BOTH THE INVASIVE AND IN SITU COMPONENTS.
- MICROCALCIFICATIONS: ABSENT.
- VENOUS / LYMPHATIC INVASION: ABSENT.
- MARGINS: NEGATIVE.
- DISTANCE OF TUMOR FROM NEAREST MARGIN IS 0.1 CM, FROM THE SUPERFICIAL (GREEN INKED) MARGIN. (MEASURED MICROSCOPICALLY) (SLIDE B6)
- INTRADUCTAL COMPONENT: PRESENT. DUCTAL CARCINOMA; HIGH NUCLEAR GRADE (GRADE III); SOLID SUBTYPE WITH CENTRAL NECROSIS.
- LYMPH NODES: ONE (1) NEGATIVE FOR TUMOR. (SEE PART A)
- NIPPLE INVOLVEMENT: ABSENT.
- SKIN INVOLVEMENT: ABSENT.
- MULTICENTRICITY: ABSENT.
- ESTROGEN RECEPTORS: NEGATIVE (SEE CASE
- PROGESTERONE RECEPTORS: NEGATIVE (SEE CASE
- HER 2 NEU by IHC: NEGATIVE (SEE CASE
- PATHOLOGIC STAGE: pT2 N0(i-) MX
- ADDITIONAL PATHOLOGIC CHANGES:
- * INTRADUCTAL PAPILLOMA.
- * FIBROADENOMATOUS CHANGES.
- * FIBROCYSTIC CHANGES.

COMMENT: Cytokeratin staining of part A supports the above diagnosis. This case received prospective intradepartmental peer review.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient: _____

Specimen #: _____

FINAL DIAGNOSIS (continued):

**** Report Electronically Signed Out ****

=====

CLINICAL DIAGNOSIS AND HISTORY:

yr old with left breast cancer

PRE-OPERATIVE DIAGNOSIS:

none provided

POST-OPERATIVE DIAGNOSIS:

none provided

GROSS DESCRIPTION:

A: Received fresh, labeled with the patient's name, [redacted] and designated "Sentinel Node #1 with markings; suture marks hottest point at 1152 hours" is a 2.5 x 2.5 x 0.7 cm irregular portion of soft tissue. Sectioning reveals a 2.5 x 1.5 x 0.5 cm pink-tan lymph node with attached adipose tissue. The specimen is entirely submitted as follows:
Cassette Summary: A1- sentinel lymph node; A2- adipose tissue.
At the time of submission the specimen will have been in formalin for approximately 23 hours** **Matched sections of cassette A1 are submitted in OCT for Protocol.****

B: Received fresh, labeled with the patient's name, [redacted] and designated "Left Breast Tissue, long-lateral, short-superior 1 pm" is a 468 gm left mastectomy specimen oriented with a short stitch at the superior aspect and long stitch at the lateral aspect. The specimen measures 20.0 cm from superior to inferior by 18.0 cm from medial to lateral by 3.0 cm from anterior to posterior. The darkly pigmented skin ellipse measures 9.5 x 3.5 cm and displays a 1.5 cm centrally located, everted nipple free of discharge. The deep margin is inked in black, and the left outer quadrant superficial margin is inked in green. Serial sectioning reveals a well-circumscribed 2.2 x 2.0 x 1.8 cm mass in the lower outer quadrant located 0.3 cm from the superficial margin and 0.7 cm from the deep margin. The cut surface is firm gritty pink-red and focally congested. The remainder of the specimen is composed of evenly distributed pink-tan fibrous tissue admixed adipose tissue. No additional lesions are identified. No lymph nodes are identified within the specimen.

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient: _____

Specimen #:

GROSS DESCRIPTION (continued):

Representative sections are submitted. At the time of submission the specimen has fixed in formalin for approximately 21 hours.
Cassette Summary: B1- skin; B2-B3- lower outer quadrant deep margin; B4-B6- mass with superficial margin; B7- representative section of grossly normal breast parenchyma from the upper outer quadrant; B8- representative section of grossly normal breast parenchyma from the upper inner quadrant; B9 representative section of grossly normal breast parenchyma from the lower inner quadrant; B10- representative section of grossly normal breast parenchyma from the lower outer quadrant; B11- representative section of grossly normal breast parenchyma from the central area; B12- representative section of nipple with associated subcutaneous tissue.
Matched sections of cassette B1, B4-B5, B7-B11 are submitted in OCT for Protocol**.

Source: NCI Genomic Data Commons file 02a4f174-e5b6-4aa4-9c8b-9a02e85f4ceb (TCGA-A2-A3XX.770EEADF-19CD-4AB9-A7FA-1A05EE17984C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).